Somatic mutation profile of tumor specimen TCGA-77-8154-01A (aliquot TCGA-77-8154-01A-11D-2244-08) from TCGA case TCGA-77-8154, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 67.5 years (24,640 days).
Specimen TCGA-77-8154-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20766fb7-c2ec-4b40-99ac-98bc4e615f35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-8154-10A (Blood Derived Normal), aliquot TCGA-77-8154-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3643adeb-8c95-4683-8457-d4e992477d52

The open-access MAF lists 225 somatic variants for this specimen: 174 protein-altering or splice-affecting, 47 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 147, Silent 47, Nonsense Mutation 13, Frame Shift Del 7, Splice Site 4, Splice Region 2, Intron 2, In Frame Del 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.832C>G p.P278A | Missense Mutation (SNP) | VAF 17/32 reads (53%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AC008397.2 | c.1037T>A p.L346H | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99441865; called by muse, mutect2, varscan2
- ACAT1 | c.1162G>T p.G388W | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99759280; called by muse, mutect2, varscan2
- AGL | c.1369G>C p.A457P | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99649489; called by muse, mutect2, varscan2
- AKR7A2 | c.353G>A p.S118N | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV99352075; called by muse, mutect2, varscan2
- ALOX15B | c.1701G>T p.M567I | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.189); catalogued as COSV101205641; called by muse, mutect2, varscan2
- AMER1 | c.3356C>T p.S1119F | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100366565; called by muse, mutect2, varscan2
- APLNR | c.1016G>A p.S339N | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.051); catalogued as COSV57241575; called by muse, mutect2, varscan2
- AQP8 | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 33/665 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.124); catalogued as rs753870432, COSV99564005; called by muse, mutect2
- AQP8 | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 36/797 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs536376309, COSV99564010; called by muse, mutect2
- ARFGAP1 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100796693; called by muse, mutect2, varscan2
- ARHGAP33 | c.2044G>T p.G682* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV99138792; called by muse, mutect2, varscan2
- ATF7 | c.100A>G p.T34A | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100129539; called by muse, mutect2, varscan2
- ATG12 | c.364-2A>T p.X122_splice | Splice Site (SNP) | VAF 5/8 reads (63%) | catalogued as rs1325331173, COSV99174636; called by muse, mutect2, varscan2
- ATP10A | c.1782G>C p.R594S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.349); catalogued as COSV100791356, COSV63517353; called by muse, mutect2, varscan2
- BCL11A | c.1387G>T p.E463* (on ENST00000335712 / NM_001365609.1; = p.E497* on NM_018014.4) | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100185898; called by muse, varscan2
- BCLAF1 | c.1565G>T p.R522L | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100786747; called by muse, mutect2, varscan2
- BMS1 | c.919G>C p.V307L | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.044); catalogued as COSV100996738; called by muse, mutect2, varscan2
- BSX | c.143G>T p.R48L | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs867300572, COSV100545259; called by muse, mutect2, varscan2
- CACNA1C | c.1581C>A p.Y527* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100219652; called by muse, mutect2
- CAPZA3 | c.64G>C p.A22P | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.495); catalogued as COSV56854759, COSV99856502, COSV99856531; called by muse, mutect2, varscan2
- CCT8L2 | c.238C>A p.L80M | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV100742848; called by muse, mutect2, varscan2
- CD247 | c.163T>C p.F55L | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.017); catalogued as COSV100758412; called by muse, mutect2, varscan2
- CDH13 | c.956G>C p.R319P | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99227344, COSV99232011; called by muse, mutect2, varscan2
- CDH18 | c.1014G>T p.E338D | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV56900111; called by muse, mutect2, varscan2
- CHRNA4 | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1306570893, COSV100937444, COSV64719632; called by muse, mutect2, varscan2
- CLASP1 | c.2093G>T p.G698V | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.594); catalogued as COSV99755426; called by muse, mutect2, varscan2
- CLEC9A | c.239T>A p.L80Q | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.896); catalogued as COSV100872829; called by muse, mutect2, varscan2
- CLPB | c.1660C>T p.R554W | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs200299650, COSV99578253; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNBD1 | c.699C>A p.H233Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV72976635; called by muse, mutect2, varscan2
- CNOT11 | c.1217A>T p.H406L | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99179318; called by muse, mutect2, varscan2
- CNTLN | c.2797G>T p.D933Y | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV99264617, COSV99265034; called by muse, varscan2
- COL11A2 | c.2852C>T p.P951L (on ENST00000341947 / NM_080680.3; = p.P844L on NM_080679.2) | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100554191; called by muse, mutect2, varscan2
- CPA5 | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs782451828, COSV62570161; called by muse, mutect2, varscan2
- CPQ | c.676G>A p.V226M | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs564531366, COSV55143433, COSV55155833; called by muse, mutect2, varscan2
- CPS1 | c.2053A>T p.I685F | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99243344; called by muse, mutect2, varscan2
- CR1 | c.2273G>A p.R758H | Missense Mutation (SNP) | VAF 100/272 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770372494, COSV100887732; called by muse, mutect2, varscan2
- CSH2 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 64/95 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs199559036, COSV61080575; called by muse, mutect2, varscan2
- CYFIP1 | c.2032G>A p.A678T | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as rs541693635; called by muse, mutect2, varscan2
- DCDC1 | c.1043A>T p.D348V | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV100663710; called by muse, mutect2, varscan2
- DDX20 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100865944; called by muse, mutect2, varscan2
- DHDDS | c.926G>T p.R309L (on ENST00000236342 / NM_001319959.1; = p.R310L on NM_024887.3) | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99360441; called by muse, mutect2, varscan2
- DLC1 | c.160C>A p.R54S | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.09); catalogued as COSV99363842; called by muse, mutect2, varscan2
- DNAH3 | c.5897C>T p.T1966I | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as rs758642151, COSV99768392; called by muse, mutect2, varscan2
- DNAH9 | c.3880C>A p.Q1294K | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as COSV99306458; called by muse, mutect2, varscan2
- DNASE2B | c.1041C>A p.Y347* | Nonsense Mutation (SNP) | VAF 21/84 reads (25%) | catalogued as COSV101042111; called by muse, mutect2, varscan2
- DNASE2B | c.1042C>T p.Q348* | Nonsense Mutation (SNP) | VAF 21/82 reads (26%) | catalogued as COSV101042112; called by muse, mutect2, varscan2
- DOCK2 | c.3400C>G p.L1134V | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as COSV99913379; called by muse, mutect2
- DOCK3 | c.3278C>T p.P1093L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs745982691, COSV56521395; called by muse, mutect2, varscan2
- DPT | c.37G>T p.V13F | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV100892150; called by muse, mutect2, varscan2
- DYNC2I1 | c.62A>G p.H21R | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs1445294008, COSV101237850; called by muse, mutect2, varscan2
- DYSF | c.2240A>G p.H747R | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.029); catalogued as COSV99248085; called by muse, mutect2, varscan2
- EIF4G3 | c.1736A>G p.N579S | Missense Mutation (SNP) | VAF 139/376 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs775097024, COSV99944725; called by muse, mutect2, varscan2
- ENC1 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.876); catalogued as rs866443122, COSV100187865; called by muse, mutect2, varscan2
- ERBB4 | c.3068T>C p.L1023S | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100726267; called by muse, mutect2, varscan2
- ERICH3 | c.2704G>C p.A902P | Missense Mutation (SNP) | VAF 69/244 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV100444786; called by muse, mutect2, varscan2
- FAM171B | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV100488723; called by muse, mutect2, varscan2
- FCHO1 | c.2051C>T p.T684I | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV99406208; called by muse, mutect2, varscan2
- FLG2 | c.4687C>G p.Q1563E | Missense Mutation (SNP) | VAF 112/359 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV101165963; called by muse, mutect2, varscan2
- FLNC | c.912C>G p.D304E | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV100368298; called by muse, mutect2, varscan2
- FMNL3 | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs749938194, COSV53302752; called by muse, mutect2, varscan2
- FOLR2 | c.661A>T p.R221W | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99995484; called by muse, mutect2, varscan2
- FPR2 | c.655A>T p.I219F | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100389320; called by muse, mutect2, varscan2
- FSHR | c.1346C>A p.T449N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28928870, CM031989, CM1514360, COSV100437456; called by muse, mutect2, varscan2
- GALT | c.131T>G p.V44G | Missense Mutation (SNP) | VAF 82/182 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101122771; called by muse, mutect2, varscan2
- GLRA3 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56857751, COSV99927722; called by muse, mutect2, varscan2
- GRIK2 | c.527A>G p.Y176C | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100027213; called by muse, mutect2, varscan2
- GYPE | c.43G>T p.V15L | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.061); catalogued as COSV100679343; called by muse, mutect2, varscan2
- H1-3 | c.49A>T p.K17* | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as COSV99768786; called by muse, mutect2, varscan2
- HCN1 | c.2464G>T p.V822F | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.068); catalogued as COSV57498710; called by muse, mutect2, varscan2
- HCN1 | c.1975C>A p.R659S | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.024); catalogued as rs745561895, COSV100300999, COSV57533051; called by muse, mutect2, varscan2
- HECTD2 | c.1951-1G>T p.X651_splice | Splice Site (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99978698; called by muse, mutect2, varscan2
- HYDIN | c.14803C>T p.Q4935* | Nonsense Mutation (SNP) | VAF 156/442 reads (35%) | catalogued as COSV101125115; called by muse, mutect2, varscan2
- IGF2R | c.380A>G p.Q127R | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.861); catalogued as rs1197543312, COSV100807611; called by muse, mutect2, varscan2
- IGFN1 | c.3055G>T p.V1019L (on ENST00000295591 / NM_001367841.1; = p.V3476L on NM_001164586.2) | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.68); catalogued as COSV99812757; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1268A>T p.E423V | Missense Mutation (SNP) | VAF 49/80 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100781534; called by muse, mutect2, varscan2
- IL1RL1 | c.1172C>A p.T391K | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as COSV99294229; called by muse, mutect2, varscan2
- IPO5 | c.1231C>A p.P411T | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV99847423; called by muse, mutect2, varscan2
- ITGA9 | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 47/78 reads (60%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as rs544515716, COSV53247579; called by muse, mutect2, varscan2
- KAT6B | c.2551C>T p.Q851* | Nonsense Mutation (SNP) | VAF 58/168 reads (35%) | catalogued as COSV99768363; called by muse, mutect2, varscan2
- KHDRBS3 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as rs751628299, COSV100878809, COSV100879099; called by muse, mutect2, varscan2
- KIAA1958 | c.195A>T p.R65S | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV100516206; called by muse, mutect2, varscan2
- KIRREL1 | c.1846T>C p.S616P | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as COSV100779983; called by muse, mutect2
- KLHDC7B | c.1112G>T p.C371F (on ENST00000395676; = p.C1012F on NM_138433.5) | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV101192958; called by muse, mutect2, varscan2
- KLHL4 | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV100909837; called by muse, mutect2, varscan2
- KNDC1 | c.2932G>T p.E978* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as COSV100465316; called by muse, mutect2, varscan2
- KRTAP26-1 | c.419C>A p.P140H | Missense Mutation (SNP) | VAF 67/213 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.864); catalogued as COSV62128571; called by muse, mutect2, varscan2
- KRTAP9-2 | c.10T>A p.C4S | Missense Mutation (SNP) | VAF 28/331 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV66646350; called by muse, mutect2
- LCE1E | c.165C>G p.S55R | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.166); catalogued as COSV100908558; called by muse, mutect2, varscan2
- LCN2 | c.221C>A p.T74N | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.336); catalogued as COSV99478238; called by muse, mutect2, varscan2
- LETM2 | c.276G>T p.Q92H (on ENST00000379957 / NM_001286819.2; = p.Q45H on NM_144652.3) | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV99907480; called by muse, mutect2
- LUZP2 | c.552A>T p.K184N | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100420289, COSV100421864; called by muse, mutect2, varscan2
- MAN1A1 | c.643T>A p.W215R | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100870388; called by muse, mutect2, varscan2
- MAP1S | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.563); catalogued as COSV100141087; called by muse, mutect2, varscan2
- MARCHF1 | c.287C>A p.P96H (on ENST00000274056; = p.P79H on NM_017923.4) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99921527; called by muse, mutect2, varscan2
- MARCHF1 | c.286C>A p.P96T (on ENST00000274056; = p.P79T on NM_017923.4) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99921528; called by muse, mutect2, varscan2
- MATN2 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99646525, COSV99647330; called by muse, mutect2, varscan2
- MBD1 | c.1238G>T p.R413L (on ENST00000269468 / NM_001323950.1; = p.R357L on NM_002384.2) | Missense Mutation (SNP) | VAF 75/195 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.131); catalogued as COSV99496576; called by muse, mutect2, varscan2
- MCF2 | c.2636G>A p.W879* | Nonsense Mutation (SNP) | VAF 84/135 reads (62%) | catalogued as COSV100644856; called by muse, mutect2, varscan2
- MCMDC2 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.73); catalogued as rs777348526, COSV100552078; called by muse, mutect2, varscan2
- MCTP2 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs149453237, COSV100537553; called by muse, mutect2, varscan2
- MMP16 | c.709+1del p.X237_splice | Splice Site (DEL) | VAF 13/61 reads (21%) | catalogued as COSV54195718; called by mutect2, pindel, varscan2
- MMS19 | c.1978G>T p.V660F | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100512928; called by muse, mutect2, varscan2
- MROH2B | c.3829A>G p.N1277D | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.16); catalogued as COSV101270763; called by muse, varscan2
- MUC1 | c.3616G>T p.A1206S (on ENST00000611571 / NM_001371720.1; = p.A217S on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.237); catalogued as rs1387815442, COSV100104506; called by muse, mutect2, varscan2
- MYCBPAP | c.457G>C p.G153R | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.858); catalogued as COSV100088458; called by muse, mutect2, varscan2
- NIPBL | c.3792A>T p.K1264N | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV99241136; called by muse, mutect2, varscan2
- NOD2 | c.2460G>T p.L820= | Splice Region (SNP) | VAF 52/183 reads (28%) | catalogued as rs1255412782, COSV100318665, COSV100318690; called by muse, mutect2, varscan2
- NR1D1 | c.915C>A p.D305E | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.109); catalogued as COSV99225578; called by muse, mutect2, varscan2
- NRCAM | c.1132G>A p.G378R (on ENST00000379028 / NM_001371124.1; = p.G372R on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100694472, COSV100694901; called by muse, mutect2, varscan2
- NRSN1 | c.527A>C p.E176A | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV101027310; called by muse, mutect2, varscan2
- NXPH1 | c.623C>A p.T208K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0.017); catalogued as COSV68312539; called by muse, mutect2, varscan2
- OPRK1 | c.246C>G p.F82L | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV99654176; called by muse, mutect2, varscan2
- OR10J1 | c.75C>G p.I25M | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV101419911, COSV71128771; called by muse, mutect2, varscan2
- OR2T2 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100737711; called by muse, mutect2, varscan2
- OR4A15 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV59037955; called by muse, mutect2, varscan2
- OR5K4 | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as COSV61583445; called by muse, mutect2, varscan2
- OTOGL | c.1998C>A p.N666K (on ENST00000547103; = p.N657K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as COSV101509372; called by muse, mutect2, varscan2
- OXER1 | c.1231G>C p.G411R | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV99685425; called by muse, mutect2, varscan2
- PCLO | c.12768G>A p.M4256I | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1362193454, COSV100433963, COSV61630371; called by muse, mutect2, varscan2
- PLEKHM3 | c.1636G>A p.D546N | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.46); catalogued as COSV101216681; called by muse, mutect2, varscan2
- PNLIPRP1 | c.404A>T p.Q135L | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100724439, COSV62610810; called by muse, mutect2, varscan2
- PPP1R36 | c.307T>C p.S103P | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.663); catalogued as COSV100072917; called by muse, mutect2, varscan2
- PPP2R5D | c.896A>C p.E299A | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99776575; called by muse, mutect2, varscan2
- PRDM14 | c.363C>G p.Y121* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as COSV52575522; called by muse, mutect2, varscan2
- PRKCB | c.769G>T p.G257* | Nonsense Mutation (SNP) | VAF 21/354 reads (6%) | catalogued as COSV100334468; called by muse, mutect2
- PRLH | c.122G>C p.W41S | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99382194, COSV99382210; called by muse, mutect2, varscan2
- PRLR | c.920A>G p.Y307C | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99184488; called by muse, mutect2, varscan2
- PTPN9 | c.737G>T p.W246L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100144387; called by muse, mutect2, varscan2
- RACGAP1 | c.1477G>T p.V493F | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as COSV100407846; called by muse, mutect2, varscan2
- RBPMS | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99824124; called by muse, mutect2, varscan2
- RNF139 | c.232A>C p.K78Q | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.757); catalogued as COSV99413499; called by muse, mutect2, varscan2
- ROBO3 | c.3074C>T p.A1025V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1189571607, COSV67299601; called by muse, mutect2
- RPL3L | c.437T>A p.L146Q | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99238299; called by muse, mutect2, varscan2
- RXFP1 | c.756G>C p.L252= | Splice Region (SNP) | VAF 10/46 reads (22%) | catalogued as COSV100313871; called by muse, mutect2, varscan2
- SCN5A | c.3515G>A p.C1172Y (on ENST00000333535 / NM_198056.3; = p.C1171Y on NM_000335.5) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100349081; called by muse, mutect2, varscan2
- SLC12A4 | c.661A>T p.I221F | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100311892; called by muse, mutect2, varscan2
- SLC19A3 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99295923; called by muse, mutect2, varscan2
- SLC25A13 | c.845G>T p.R282M | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.416); catalogued as COSV99673780; called by muse, mutect2, varscan2
- SLC43A1 | c.146C>A p.T49K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs755349217, COSV99561068; called by muse, varscan2
- SLITRK3 | c.2513C>T p.P838L | Missense Mutation (SNP) | VAF 56/284 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as rs755072192, COSV99579501; called by muse, mutect2, varscan2
- SMG1 | c.5571G>T p.L1857F | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV101246292; called by muse, mutect2, varscan2
- SMG9 | c.910-1G>A p.X304_splice | Splice Site (SNP) | VAF 13/37 reads (35%) | catalogued as COSV99526786; called by muse, mutect2, varscan2
- SNRNP200 | c.4888C>T p.R1630C | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV60495083; called by muse, mutect2, varscan2
- SOGA3 | c.2387G>T p.R796L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV100846970, COSV64106342; called by muse, mutect2, varscan2
- SP140 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763966598, COSV59451528; called by muse, mutect2, varscan2
- SPAG17 | c.4399G>T p.D1467Y | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100309517; called by muse, mutect2, varscan2
- SPATA31E1 | c.2266C>A p.P756T | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.637); catalogued as COSV100350626; called by muse, mutect2, varscan2
- SULT1C2 | c.435del p.M146* | Frame Shift Del (DEL) | VAF 38/134 reads (28%) | catalogued as COSV99265097, COSV99265220; called by mutect2, pindel, varscan2
- TBCE | c.298A>G p.K100E | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as rs770233453, COSV100783143; called by muse, mutect2, varscan2
- TDRD6 | c.4935A>T p.L1645F | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV100287834; called by muse, mutect2, varscan2
- TENM3 | c.5763C>A p.N1921K | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as rs764221618, COSV101305209; called by muse, mutect2, varscan2
- TESMIN | c.1323C>A p.F441L | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV99663779; called by muse, mutect2, varscan2
- TLDC2 | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV99456001; called by muse, mutect2, varscan2
- TMEM63C | c.326G>C p.W109S | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100029521, COSV53607983; called by muse, mutect2, varscan2
- TSEN34 | c.676G>T p.D226Y | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99044401, COSV99824889; called by muse, mutect2, varscan2
- TTN | c.89026G>A p.E29676K (on ENST00000591111; = p.E22252K on NM_003319.4) | Missense Mutation (SNP) | VAF 50/163 reads (31%) | PolyPhen benign (0.018); catalogued as COSV100618611; called by muse, mutect2
- TTN | c.89024T>G p.I29675S (on ENST00000591111; = p.I22251S on NM_003319.4) | Missense Mutation (SNP) | VAF 49/157 reads (31%) | PolyPhen possibly damaging (0.663); catalogued as COSV100618612; called by muse, mutect2
- TTN | c.541A>G p.S181G | Missense Mutation (SNP) | VAF 62/190 reads (33%) | PolyPhen benign (0.189); catalogued as COSV100618615; called by muse, mutect2, varscan2
- UBR3 | c.5126C>T p.P1709L | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV99774355; called by muse, mutect2, varscan2
- VTI1B | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.659); catalogued as COSV99373785; called by muse, mutect2, varscan2
- VWA3A | c.1714C>A p.Q572K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV100241013; called by muse, mutect2, varscan2
- ZRANB1 | c.1118A>G p.Y373C | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as rs778022551, COSV62841968; called by muse, mutect2, varscan2
- ANG | c.302A>T p.Q101L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.645); called by muse, mutect2
- BAZ2B | c.4135del p.Q1379Kfs*19 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- CDH26 | c.1195del p.Q399Rfs*29 | Frame Shift Del (DEL) | VAF 100/331 reads (30%) | called by mutect2, pindel, varscan2
- HSD3B2 | c.196_204del p.P66_L68del | In Frame Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- IGKV1D-42 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- KMT2C | c.6323_6324del p.S2108Ffs*45 | Frame Shift Del (DEL) | VAF 20/61 reads (33%) | called by pindel, varscan2
- KMT2D | c.9448del p.G3151Afs*4 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel, varscan2
- RAB11FIP2 | c.872_882del p.D291Vfs*8 | Frame Shift Del (DEL) | VAF 18/116 reads (16%) | called by mutect2, pindel, varscan2
- RYR2 | c.10761del p.W3587Cfs*14 | Frame Shift Del (DEL) | VAF 22/86 reads (26%) | called by mutect2, pindel, varscan2
- TBC1D3F | c.1321G>C p.G441R | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by mutect2, varscan2
- TRBC2 | c.512T>C p.M171T | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AC092143.1 | c.1218C>T p.Y406= | Silent (SNP) | VAF 123/428 reads (29%) | catalogued as rs541594755, COSV100205914; called by muse, mutect2, varscan2
- ADRA1A | c.615C>T p.C205= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs375583228; called by muse, mutect2, varscan2
- AGBL1 | c.3338G>A p.*1113= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV101480155; called by muse, mutect2, varscan2
- AMPH | c.1542T>A p.T514= | Silent (SNP) | VAF 50/186 reads (27%) | catalogued as COSV100342592; called by muse, mutect2, varscan2
- AMY2B | c.6G>A p.K2= | Silent (SNP) | VAF 33/162 reads (20%) | catalogued as COSV100796358; called by muse, mutect2, varscan2
- ANP32B | c.213C>A p.L71= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV100233264; called by muse, mutect2, varscan2
- C10orf53 | c.465G>A p.Q155= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV100935066; called by muse, mutect2, varscan2
- C1orf116 | c.291A>T p.P97= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV100847957; called by muse, mutect2, varscan2
- CAD | c.579C>G p.L193= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV99255266; called by muse, mutect2, varscan2
- CCT8L2 | c.237C>A p.A79= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV100742849, COSV63461705; called by muse, mutect2, varscan2
- DNAH7 | c.1773G>A p.E591= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as COSV100415900; called by muse, mutect2, varscan2
- ETS1 | c.690C>T p.V230= | Silent (SNP) | VAF 64/130 reads (49%) | catalogued as rs747494573, COSV60093526; called by muse, mutect2, varscan2
- EXPH5 | c.5940G>T p.L1980= | Silent (SNP) | VAF 59/304 reads (19%) | catalogued as COSV56202307, COSV99761819; called by muse, mutect2, varscan2
- FANCI | c.3564A>T p.G1188= (on ENST00000310775 / NM_001376911.1; = p.G1128= on NM_018193.3) | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100168170; called by mutect2, varscan2
- FNDC1 | c.3000G>A p.R1000= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV51932616, COSV99796130; called by mutect2, varscan2
- FPR2 | c.654C>A p.A218= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV100389318; called by muse, mutect2, varscan2
- GPR6 | c.126G>T p.A42= | Silent (SNP) | VAF 36/75 reads (48%) | catalogued as COSV99254402; called by muse, mutect2, varscan2
- HAO1 | c.960C>A p.G320= | Silent (SNP) | VAF 35/122 reads (29%) | catalogued as COSV101113240; called by muse, mutect2, varscan2
- HNF1A | c.1062G>A p.T354= | Silent (SNP) | VAF 99/236 reads (42%) | catalogued as rs373384579; called by muse, mutect2, varscan2
- IGHE | c.1185C>T p.A395= | Silent (SNP) | VAF 63/173 reads (36%) | called by muse, mutect2, varscan2
- IGKV1-27 | c.36C>G p.L12= | Silent (SNP) | VAF 25/106 reads (24%) | called by muse, mutect2, varscan2
- IL36A | c.186C>T p.P62= | Silent (SNP) | VAF 91/289 reads (31%) | catalogued as rs759238017, COSV99382151; called by muse, mutect2, varscan2
- KIF4B | c.2967C>T p.I989= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as rs1421365275, COSV101469343; called by muse, mutect2, varscan2
- KLHL36 | c.120T>A p.R40= | Silent (SNP) | VAF 49/172 reads (28%) | catalogued as COSV99256889; called by muse, mutect2, varscan2
- KNTC1 | c.4548T>C p.S1516= | Silent (SNP) | VAF 63/118 reads (53%) | catalogued as COSV100338463; called by muse, mutect2, varscan2
- KSR2 | c.1437C>A p.I479= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV100195620; called by muse, mutect2, varscan2
- LRRK1 | c.636C>T p.F212= | Silent (SNP) | VAF 39/132 reads (30%) | catalogued as COSV99440999; called by muse, mutect2, varscan2
- MYPN | c.894T>A p.P298= | Silent (SNP) | VAF 23/82 reads (28%) | catalogued as COSV100590140; called by muse, mutect2, varscan2
- NAB1 | c.300A>G p.P100= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as rs778763073, COSV100493060; called by muse, mutect2, varscan2
- NLRX1 | c.978C>T p.L326= | Silent (SNP) | VAF 69/297 reads (23%) | catalogued as COSV52708514; called by muse, mutect2, varscan2
- NOL8 | c.1458C>T p.L486= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100694597; called by muse, mutect2, varscan2
- OLIG3 | c.339G>T p.A113= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as rs142649210, COSV100880293, COSV62988200; called by muse, mutect2, varscan2
- PDE1A | c.960G>T p.R320= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as rs748629617, COSV100114980, COSV59525904; called by muse, mutect2, varscan2
- PGA5 | c.960C>T p.I320= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs754153615, COSV56715286; called by muse, varscan2
- PPP3CA | c.222G>A p.Q74= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as rs1363401176, COSV100547809; called by muse, mutect2, varscan2
- PREX1 | c.261G>A p.V87= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV100906503; called by muse, mutect2, varscan2
- RAD51AP2 | c.3189T>C p.N1063= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV101208370; called by muse, mutect2, varscan2
- RIMBP2 | c.2019C>A p.A673= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV99899251; called by muse, mutect2
- SIGLEC5 | c.651C>A p.R217= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV99707627; called by muse, mutect2, varscan2
- SLC6A13 | c.1557C>T p.T519= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV100569997; called by muse, mutect2, varscan2
- SYNCRIP | c.636A>C p.T212= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as COSV62288268; called by muse, mutect2, varscan2
- TBX15 | c.999C>T p.D333= (on ENST00000369429 / NM_001330677.2; = p.D227= on NM_152380.3) | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV99254346; called by muse, mutect2, varscan2
- TPR | c.2823A>G p.L941= | Silent (SNP) | VAF 62/196 reads (32%) | catalogued as rs1211849854, COSV100824029; called by muse, mutect2, varscan2
- TREML4 | c.547A>C p.R183= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV100422934; called by muse, mutect2
- TREML4 | c.549A>G p.R183= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV100422935; called by muse, mutect2
- UNC5C | c.2382T>C p.V794= | Silent (SNP) | VAF 29/109 reads (27%) | catalogued as COSV101497940; called by muse, mutect2, varscan2
- USH2A | c.9363C>T p.I3121= | Silent (SNP) | VAF 40/166 reads (24%) | catalogued as COSV100237521; called by muse, mutect2, varscan2
- AC244258.1 | n.362C>A | RNA (SNP) | VAF 43/135 reads (32%) | catalogued as rs372270692; called by muse, mutect2, varscan2
- HIC2 | c.*2A>C | 3'UTR (SNP) | VAF 7/127 reads (6%) | catalogued as COSV101335599; called by muse, mutect2
- MARCHF1 | c.-322-85479G>T | Intron (SNP) | VAF 4/10 reads (40%) | catalogued as COSV72276598; called by muse, mutect2
- PAXIP1 | c.325-2718G>A | Intron (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
